Gene-level copy-number profile of tumor specimen C3L-00898-02 from CPTAC case C3L-00898, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,081 days).
Specimen C3L-00898-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40d15f1e-477e-48be-8f79-b62e898b246f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00898-72 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,675 have no estimate.
https://portal.gdc.cancer.gov/files/294c6918-5b72-4733-a62b-394743322b53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,079; copy number 1: 6,168; copy number 2: 42,936; copy number 3: 4,639; copy number 4: 947; copy number 5: 762; copy number 6: 510; copy number 7: 404; copy number 8: 195; copy number 9: 106; copy number 10: 42; copy number 11: 43; copy number 12: 26; copy number 13: 16; copy number 14: 6; copy number 15: 5; copy number 16: 3; copy number 17: 5; copy number 18: 3; copy number 19: 6; copy number 20: 5; copy number 21: 3; copy number 23: 2; copy number 24: 3; copy number 25: 3; copy number 26: 6; copy number 29: 2; copy number 30: 1; copy number 34: 2; copy number 35: 2; copy number 36: 2; copy number 42: 2; copy number 51: 1; copy number 60: 3; copy number 62: 3; copy number 64: 1; copy number 67: 1; copy number 68: 1; copy number 246: 2; copy number 471: 1; copy number 1201: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,011 genes in 588 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,843,812–11,848,345, 4 genes: AL021155.2, AL021155.3, NPPA, AL021155.1.
- chr1:25,222,276–25,362,361, 8 genes (within-gene range 0–1): SYF2, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A.
- chr1:27,669,468–27,703,063, 4 genes (within-gene range 0–3): AL445490.1, RNU6-949P, CHMP1AP1, RNU6-424P.
- chr1:43,354,684–43,368,074, 4 genes: AL139289.1, CDC20, ELOVL1, MIR6734.
- chr1:43,389,882–43,456,995, 5 genes: SZT2, SZT2-AS1, MIR6735, HYI, HYI-AS1.
- chr1:48,325,080–48,448,042, 4 genes (within-gene range 0–4): PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P.
- chr1:51,287,258–51,519,266, 6 genes (within-gene range 0–8): TTC39A, TTC39A-AS1, EPS15, AL671986.1, RNU6-877P, AC104170.1.
- chr2:175,167,633–175,184,607, 5 genes (within-gene range 0–8): MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14.
- chr2:219,069,357–219,185,475, 6 genes (within-gene range 0–4): NHEJ1, AC068946.1, RN7SL764P, SLC23A3, CNPPD1, RETREG2.
- chr3:119,294,383–119,420,714, 4 genes (within-gene range 0–7): ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P.
- chr5:58,453,982–58,558,243, 5 genes: PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108.
- chr7:74,796,144–74,913,310, 5 genes: GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P.
- chr8:30,082,758–30,177,208, 5 genes (within-gene range 0–7): AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2.
- chr10:35,638,249–35,698,037, 4 genes: FZD8, AL121749.2, MIR4683, RPL7P37.
- chr10:87,009,785–87,041,341, 4 genes (within-gene range 0–2): AL136982.2, FAM25A, AL136982.5, RNU6-529P.
- chr10:100,150,094–100,234,398, 4 genes (within-gene range 0–2): ERLIN1, CHUK, AL138921.2, AL138921.1.
- chr11:47,164,299–47,186,443, 4 genes (within-gene range 0–5): ARFGAP2, AC090589.3, PACSIN3, MIR6745.
- chr11:48,245,056–48,366,465, 6 genes: OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5.
- chr11:49,898,267–49,923,886, 5 genes: OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P.
- chr11:54,603,069–54,683,821, 7 genes: OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8.
- chr11:54,706,832–55,344,231, 9 genes: OR4A5, OR4A6P, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16.
- chr11:62,662,817–62,679,117, 6 genes (within-gene range 0–7): C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1.
- chr11:62,761,565–62,806,302, 5 genes (within-gene range 0–1): POLR2G, TMEM179B, MIR6748, NXF1, MIR6514.
- chr11:62,853,663–62,888,875, 7 genes: SNORD30, SNORD22, SNORD28, SNORD27, SNORD26, SNORD25, SLC3A2.
- chr12:55,293,988–55,343,774, 5 genes: OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P.
- chr12:55,818,041–55,842,966, 4 genes (within-gene range 0–5): ORMDL2, DNAJC14, TMEM198B, MMP19.
- chr14:24,180,219–24,232,367, 13 genes (within-gene range 0–4): IPO4, AL136295.4, AL136295.22, TM9SF1, AL136295.1, AL136295.6, AL136295.7, TSSK4, CHMP4A, AL096870.2, MDP1, NEDD8-MDP1, NEDD8.
- chr14:24,239,643–24,299,780, 6 genes: TINF2, TGM1, RABGGTA, AL096870.12, AL096870.10, DHRS1.
- chr16:18,397,937–18,562,211, 10 genes (within-gene range 0–1): Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2.
- chr16:52,078,622–52,099,120, 4 genes: AC009039.1, AC009039.2, LINC00919, LINC02180.
- chr16:66,720,893–66,754,740, 5 genes (within-gene range 0–2): DYNC1LI2, AC018557.1, AC018557.3, AC018557.2, AC044802.1.
- chr16:70,802,084–71,289,715, 5 genes (within-gene range 0–4): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1, CMTR2.
- chr16:71,845,976–71,931,199, 5 genes (within-gene range 0–6): ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1.
- chr16:72,008,588–72,112,912, 6 genes (within-gene range 0–6): DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38.
- chr17:76,470,891–76,561,705, 5 genes: RHBDF2, CYGB, AC015802.3, SNORD1B, SNORD1A.
- chr21:30,337,013–30,396,822, 5 genes: KRTAP27-1, KRTAP23-1, KRTAP13-2, MIR4327, KRTAP13-1.
- chr21:30,741,780–30,807,119, 6 genes: KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1, KRTAP8-2P, KRTAP8-3P.
- chr21:36,130,489–36,175,815, 4 genes (within-gene range 0–4): MEMO1P1, CBR3-AS1, RPS9P1, CBR3.
- chr22:26,443,423–26,514,568, 4 genes (within-gene range 0–3): HPS4, SRRD, TFIP11, Z95115.1.
- chr22:40,346,500–40,410,289, 4 genes (within-gene range 0–4): ADSL, AL022238.3, SGSM3, SGSM3-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,097 genes in 878 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,487,627, 9 genes, copy number 5–12 (within-gene range 5–18): PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1.
- chr1:7,219,360–7,700,970, 7 genes, copy number 5 (within-gene range 5–20): RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1.
- chr1:24,899,511–25,209,437, 9 genes, copy number 5–20: RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1.
- chr2:9,583,967–9,950,817, 9 genes, copy number 6–8 (within-gene range 4–8): YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.3, TAF1B, AC010969.2, AC010969.3.
- chr2:96,859,718–97,018,604, 8 genes, copy number 5–7 (within-gene range 5–16): SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1.
- chr2:97,281,356–97,434,847, 12 genes, copy number 7: AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2.
- chr2:230,836,909–230,996,032, 8 genes, copy number 5–10: AC012507.2, ITM2C, GCSIR, GPR55, AC012507.1, AC012507.3, COX20P2, SPATA3-AS1.
- chr3:106,894,352–106,902,523, 10 genes, copy number 6: MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14.
- chr3:177,441,910–177,959,817, 9 genes, copy number 5–9: LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2.
- chr5:1,855,970–2,715,237, 11 genes, copy number 5–11: LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, AC092266.1, LSINCT5.
- chr5:18,886,622–19,234,487, 8 genes, copy number 5–6: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:176,143,078–176,361,807, 10 genes, copy number 5–7 (within-gene range 5–8): AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1, SIMC1, BRCC3P1, KIAA1191, AC138956.1, AC138956.2.
- chr6:40,334,775–40,715,363, 8 genes, copy number 6–11 (within-gene range 0–14): TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1.
- chr7:5,428,731–5,781,696, 10 genes, copy number 6–13 (within-gene range 6–22): AC092171.5, FBXL18, AC092171.2, MIR589, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874.
- chr8:20,941,428–21,309,486, 8 genes, copy number 5–11: AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1, AC021613.2, AC021355.1.
- chr8:29,527,312–29,953,724, 10 genes, copy number 5–8: AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209.
- chr8:134,764,809–135,456,952, 10 genes, copy number 5–12: AC087045.3, AC083843.3, AC083843.2, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1.
- chr10:2,098,167–3,066,001, 11 genes, copy number 5–9: RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AC026396.1, AL731533.1, AL731533.2.
- chr10:10,174,230–11,336,675, 10 genes, copy number 5–9 (within-gene range 0–9): ELOCP3, Y_RNA, CUX2P1, AL583859.1, CELF2-DT, AL583859.2, AL136452.1, SFTA1P, CELF2, LINC00710.
- chr12:2,018,213–2,457,392, 7 genes, copy number 7 (within-gene range 7–8): CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1.
- chr12:97,155,234–97,598,415, 16 genes, copy number 5–6 (within-gene range 5–7): AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6.
- chr12:132,899,984–133,107,544, 12 genes, copy number 6–9 (within-gene range 1–9): AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140.
- chr14:70,255,629–70,547,464, 9 genes, copy number 5–7 (within-gene range 0–9): AL356804.1, COX16, SYNJ2BP-COX16, RNU2-51P, SYNJ2BP, AL357153.2, ADAM21, ADAM20P1, RNU6-659P.
- chr14:70,581,257–70,712,153, 7 genes, copy number 7–9 (within-gene range 0–9): MED6, AL357153.3, KRT18P7, AL357153.1, RN7SL77P, TTC9, LINC01269.
- chr14:96,992,864–97,688,600, 7 genes, copy number 5–9: AL049833.3, AL049833.2, AL049833.1, LINC02304, LINC02325, LINC02291, AL163872.1.
- chr14:104,223,584–104,677,749, 10 genes, copy number 5–30 (within-gene range 2–47): LINC02691, AL512357.1, RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710.
- chr15:33,858,782–34,101,862, 7 genes, copy number 5–6 (within-gene range 1–6): AVEN, CHRM5, AC009268.2, AC009268.3, AC009268.1, EMC7, AC079203.1.
- chr15:60,479,152–61,214,231, 12 genes, copy number 5–6 (within-gene range 2–9): RORA-AS1, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1, AC012404.2.
- chr16:17,227,023–17,826,906, 7 genes, copy number 5–10: AC099494.2, AC099494.3, AC009152.6, AC009152.1, AC009152.3, AC109495.1, AC025277.1.
- chr17:15,014,805–15,272,292, 7 genes, copy number 5–10: AC005772.1, CDRT7, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2.
- chr17:37,828,305–38,192,541, 12 genes, copy number 5–7: YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3.
- chr17:58,556,678–58,985,179, 10 genes, copy number 6 (within-gene range 0–7): TEX14, U3, IGBP1P2, RNU1-108P, AC011195.1, RNU1-52P, RNVU1-34, RAD51C, AC025521.1, PPM1E.
- chr18:48,026,672–48,863,217, 9 genes, copy number 5–10 (within-gene range 0–16): ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, CTIF, AC048380.2, AC048380.3.
- chr18:78,480,549–78,979,074, 8 genes, copy number 5–18: AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896.
- chr19:29,811,991–31,554,803, 23 genes, copy number 5–14: CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841.
- chr19:33,283,978–33,557,470, 11 genes, copy number 5–62: AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1.
- chr20:50,162,765–50,578,041, 12 genes, copy number 5–10: LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, Y_RNA, AL133230.1.
- chr20:56,667,430–57,328,696, 13 genes, copy number 6–35: RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, AL122058.1, Y_RNA, MIR4325, RPL39P39.
- chr21:14,774,301–15,346,738, 11 genes, copy number 5–9 (within-gene range 0–9): GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF246928.1.
- chr22:47,612,231–48,143,229, 8 genes, copy number 6–21: LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1.

Autosomal genes at a single copy (total copy number 1): 5,965. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
